Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A5FO, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A5FO-01A (Primary Tumor).

Gross Description: There is an uterus up to 8x5x2 cm in size. Endocervix is granular. Exocervix and endocervix are up to 5x3 cm in size. They are involved by the white-gray soft tumor. Right ovary is 1.5x1 cm in size. Left ovary is grey-white dense, up to 2x4 cm in size.

Microscopic Description: Squamous cell carcinoma of the cervix, G-2, with invasion of more than 1/2 of the muscle layer and spread to the endocervix. In the right and left ovaries there are fibrous bodies. Fallopian tubes are of normal structure. Glandular-cystic endometrial polyp. Ten examined left obturator lymph nodes and eight examined right obturator lymph nodes demonstrated sclerosis and lipomatosis. Three examined presacral lymph nodes demonstrated follicular hyperplasia.

Diagnosis Details: Tumor Features: Indeterminate, Tumor Extent: Lesion less than 4.0cm, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments: Tumor size is 2x3 cm (clinical data).

Formatted Path Reports: CERVIX TISSUE CHECKLIST

Specimen type: Simple hysterectomy

Tumor site: Cervix

Tumor size: 3 x 0 x 2 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Lesion less than 4.0 cm

Lymph nodes: 0/21 positive for metastasis (Obturator, presacral 0/21)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Tumor size is 2x3 cm (clinical data).

ICD-O-3

Carcinoma, Squamous cell NOS
8070/3

Site: Cervix Uteri, cervix NOS
C53.9

QW 1/8/13

Source: NCI Genomic Data Commons file 8a912355-b6ad-4153-b00e-ecbadb43b150 (TCGA-EA-A5FO.4022C7F9-CECA-4C6B-92D5-729518405F30.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).